CCDI case PBCUJM — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/d1132b0e-6659-4500-bb91-ea3a925684f3

Demographics
Sex at birth: female.

Biospecimens (3 samples)
- Sample 0DZY4S: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DZY59: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DZY6B: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
